Somatic mutation profile of tumor specimen MP2PRT-PANEZV-TMP1-A (aliquot MP2PRT-PANEZV-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANEZV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (850 days).
Specimen MP2PRT-PANEZV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbc288c9-32e7-4c30-8af1-45aad2ee75a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANEZV-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANEZV-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43a125ea-ea17-494e-ab92-c1f1acd81cd8

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN5A | c.4931G>A p.R1644H (on ENST00000333535 / NM_198056.3; = p.R1643H on NM_000335.5) | Missense Mutation (SNP) | VAF 153/413 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs28937316, CM951143, COSV61120013; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 178/401 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs771771163, COSV104414906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR23C | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 271/560 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.08); catalogued as rs1454629960; called by muse, mutect2, varscan2
- SPEG | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 39/589 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as rs1176492727; called by muse, mutect2
- VPS52 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 44/837 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DGKD | c.2352C>T p.R784= (on ENST00000264057 / NM_152879.3; = p.R740= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 139/286 reads (49%) | catalogued as rs751829089, COSV99896300; called by muse, mutect2, varscan2
- PRDM6 | c.351G>A p.P117= | Silent (SNP) | VAF 74/1022 reads (7%) | catalogued as rs1032012755; called by muse, mutect2
- SPOCD1 | c.15G>A p.G5= | Silent (SNP) | VAF 12/343 reads (3%) | called by muse, mutect2
